Gene-level copy-number profile of tumor specimen TCGA-F4-6704-01A from TCGA case TCGA-F4-6704, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Mucinous adenocarcinoma; Tissue or organ of origin: Sigmoid colon; AJCC pathologic stage: Stage IIIC; Age at diagnosis: 60.1 years (21,949 days).
Specimen TCGA-F4-6704-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-COAD.6bf8c9c3-5b30-4b98-be21-722ec163a4c0.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-F4-6704-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 810 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/c73c950f-8ef5-42f0-99d4-f98b1cbcad62

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 15; copy number 2: 7,547; copy number 3: 16,674; copy number 4: 18,247; copy number 5: 11,085; copy number 6: 5,199; copy number 7: 458; copy number 8: 52; copy number 9: 251; copy number 10: 97; copy number 11: 72; copy number 12: 16; copy number 25: 41; copy number 30: 6; copy number 32: 53.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-F4-6704-01A-11D-1834-01): tumor purity 0.5, ploidy 3.63, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 536 genes in 10 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:15,918,350–15,942,249, 1 gene, copy number 30 (within-gene range 4–30): MYCNOS.
- chr2:15,940,550–16,105,841, 5 genes, copy number 30 (within-gene range 4–30): MYCN, RN7SL104P, AC010145.1, GACAT3, AC130710.1.
- chr4:25,861,830–25,929,874, 1 gene, copy number 9 (within-gene range 3–9): SMIM20.
- chr9:14,475–22,824,213, 325 genes, copy number 9–10 (broad region; genes not listed).
- chr9:22,747,700–22,768,316, 2 genes, copy number 10: CLIC4P1, AC017067.1.
- chr9:34,957,608–36,022,113, 69 genes, copy number 11 (broad region; genes not listed).
- chr10:110,869,743–110,900,006, 3 genes, copy number 11 (within-gene range 4–11): AL136368.1, PDCD4-AS1, PDCD4.
- chr10:121,478,332–122,345,793, 16 genes, copy number 12: FGFR2, AC009988.1, RPS15AP5, AC025947.1, ATE1, Y_RNA, ATE1-AS1, AL731566.1, AL731566.3, NSMCE4A, AL731566.2, TACC2, AC063960.1, AC063960.2, BTBD16, RNU6-728P.
- chr19:15,235,519–15,662,825, 20 genes, copy number 9 (within-gene range 6–9): BRD4, AC005776.1, AC005776.2, AKAP8, AC005785.1, AKAP8L, AC005785.2, AC006128.1, WIZ, MIR1470, RASAL3, PGLYRP2, CYP4F22, AC011492.1, CYP4F23P, AD000091.1, RPL23AP2, AC093072.1, CYP4F8, CYP4F3.
- chr20:21,742,303–25,452,628, 94 genes, copy number 25–32 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 15. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
